Somatic mutation profile of tumor specimen TCGA-V4-A9ET-01A (aliquot TCGA-V4-A9ET-01A-11D-A39W-08) from TCGA case TCGA-V4-A9ET, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 57.8 years (21,113 days).
Specimen TCGA-V4-A9ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23dae56d-d01a-47e3-a0a1-917ba9cb5fe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9ET-10A (Blood Derived Normal), aliquot TCGA-V4-A9ET-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0176137f-e4f4-4a16-9eb5-874b8735034c

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSMD3 | c.2528C>T p.A843V (on ENST00000297405 / NM_001363185.1; = p.A739V on NM_052900.3) | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336806392; called by muse, mutect2, varscan2
- BLOC1S6 | c.222C>T p.L74= | Splice Region (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- LRRTM3 | c.957T>A p.N319K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RABL6 | c.1922G>C p.S641T | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- USP13 | c.1142A>T p.Q381L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- PCDHB7 | c.1851G>A p.V617= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as rs1554280293; called by muse, mutect2, varscan2
- PYROXD2 | c.1455T>C p.D485= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2
- SLC23A3 | c.639C>G p.A213= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
